CPTAC case C3N-01857 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9b84c1a2-d24d-4085-b597-eff3d2203756

Demographics
Sex at birth: female; Race: white; Year of birth: 1947; Vital status: Dead; Days to death: 651 days (1.8 years); Year of death: 2019; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 69.6 years (25,423 days); Year of diagnosis: 2017; Last known disease status: With tumor; Days to last known disease status: 651 days (1.8 years); Progression or recurrence: yes; Days to recurrence: 413 days (1.1 years); Days to last follow up: 651 days (1.8 years).
   Pathology details: Greatest tumor dimension: 5 cm.

Follow-up (2 entries)
- Days to follow up: 357 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 651 days (1.8 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 413 days (1.1 years); Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 60 kg; Height: 164 cm; BMI: 22.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01857-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -21 days; Initial weight: 119 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01857-21: Section location: Temporal Lobe; Percent tumor nuclei: 90; Percent necrosis: 2.
- Sample C3N-01857-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -21 days; Initial weight: 169 mg; Time between excision and freezing: 7 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01857-22: Section location: Temporal Lobe; Percent tumor nuclei: 85; Percent necrosis: 2.
- Sample C3N-01857-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -21 days; Method of sample procurement: Blood Draw.
